Somatic mutation profile of tumor specimen TCGA-CF-A3MG-01A (aliquot TCGA-CF-A3MG-01A-11D-A20D-08) from TCGA case TCGA-CF-A3MG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 48.2 years (17,600 days).
Specimen TCGA-CF-A3MG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c7b629a-1664-4fc3-bcaf-7bd9f0768a29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A3MG-10A (Blood Derived Normal), aliquot TCGA-CF-A3MG-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5579cfa-858a-4fb2-9a24-6adc52f76f42

The open-access MAF lists 159 somatic variants for this specimen: 108 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 45, Nonsense Mutation 13, Frame Shift Del 3, Intron 3, RNA 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs118203402, CM090914, COSV100052877, COSV53764234, COSV53764966, COSV53768233; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV67216064; called by muse, mutect2, varscan2
- ADGRD1 | c.1325A>C p.H442P | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV55439888; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4099C>T p.R1367C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51841450; called by muse, mutect2, varscan2
- ANKRD11 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56355946, COSV99967921; called by muse, mutect2, varscan2
- ANKRD28 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); catalogued as COSV67517059; called by muse, varscan2
- ANO1 | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV60281737; called by muse, mutect2, varscan2
- ARID1A | c.3860G>C p.R1287T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61372673; called by muse, mutect2, varscan2
- ASB17 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV52409479; called by muse, varscan2
- ATRX | c.1216C>G p.H406D | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV64872282; called by muse, mutect2, varscan2
- BFAR | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV55492628; called by muse, mutect2, varscan2
- CAND1 | c.3163G>T p.E1055* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as rs1044739202; called by muse, mutect2, varscan2
- CARF | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV57546724; called by muse, mutect2, varscan2
- CCDC65 | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56739205; called by muse, mutect2, varscan2
- CCNK | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66274210; called by muse, mutect2, varscan2
- CDH8 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV54851239; called by muse, mutect2, varscan2
- CDKN1A | c.136dup p.R46Pfs*2 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | catalogued as COSV55188784, COSV55189373; called by mutect2, pindel, varscan2
- CEND1 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs762710448, COSV57192414; called by muse, mutect2, varscan2
- CHRM1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs925886937, COSV61006232, COSV61007354; called by muse, mutect2, varscan2
- COG3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV63071473; called by muse, mutect2, varscan2
- COPB2 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV60811946; called by muse, mutect2, varscan2
- CYP46A1 | c.148T>C p.W50R | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as COSV55893282; called by muse, mutect2, varscan2
- DCTN4 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV69781804; called by muse, mutect2, varscan2
- DDX54 | c.2605G>C p.G869R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as COSV58372189; called by muse, mutect2, varscan2
- EIF3I | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59084058; called by muse, mutect2, varscan2
- EIF3I | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV59084062; called by muse, varscan2
- ERC2 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs775270120, COSV55604163; called by muse, mutect2, varscan2
- FAM189B | c.1656G>C p.E552D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.543); catalogued as rs757796054, COSV59169096; called by muse, mutect2, varscan2
- FAM83C | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as rs753289930, COSV65582237; called by muse, mutect2, varscan2
- FARP2 | c.1023C>G p.F341L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50869351; called by muse, mutect2, varscan2
- FBN2 | c.5815G>A p.E1939K | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as rs779671043, COSV52495907; called by muse, mutect2, varscan2
- FBXO42 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV65044616; called by muse, mutect2, varscan2
- FGFR4 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776973649, COSV52801328; called by muse, mutect2, varscan2
- FLG | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 151/574 reads (26%) | catalogued as COSV64246305; called by muse, mutect2, varscan2
- FLG2 | c.6659G>A p.G2220E | Missense Mutation (SNP) | VAF 118/426 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV66166958, COSV66168657; called by muse, mutect2, varscan2
- GABRB3 | c.1394T>A p.L465* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV54672511, COSV54674652; called by muse, mutect2, varscan2
- GBP7 | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV54008358, COSV54012264; called by muse, varscan2
- GLYCTK | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59793129; called by muse, mutect2, varscan2
- GPR119 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 73/73 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as rs765431695, COSV52275007; called by muse, mutect2, varscan2
- GPR141 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV57731421; called by muse, mutect2, varscan2
- HDAC11 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.227); catalogued as rs772579463, COSV55472522; called by muse, mutect2, varscan2
- HMGXB4 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV53333057; called by muse, varscan2
- ITGBL1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV66021535; called by muse, mutect2, varscan2
- KCNA6 | c.1571G>C p.R524T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs773647457, COSV54974266, COSV54976414; called by muse, mutect2, varscan2
- KDM3A | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100459827, COSV57218708; called by muse, mutect2, varscan2
- KIF5C | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs770338912; called by muse, mutect2
- KMT2C | c.14646C>G p.L4882= | Splice Region (SNP) | VAF 19/80 reads (24%) | catalogued as COSV51343943; called by muse, mutect2, varscan2
- LIMK1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs965643252, COSV60280113; called by muse, mutect2, varscan2
- LLGL1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1449541989, COSV57496472; called by muse, mutect2, varscan2
- MAN1C1 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1374089517, COSV56042070; called by muse, mutect2, varscan2
- MAP3K13 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.417); catalogued as COSV53984233; called by muse, mutect2
- MTMR3 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV60302127; called by muse, mutect2, varscan2
- NGLY1 | c.1790A>G p.D597G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV54984317; called by muse, mutect2, varscan2
- NLRP8 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs771207728, COSV52583961; called by muse, mutect2
- NR4A3 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58243566; called by muse, mutect2, varscan2
- OR51S1 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV59057216, COSV59057408; called by muse, mutect2, varscan2
- OR5H6 | c.141C>G p.F47L (on ENST00000642105; = p.F31L on NM_001005479.2) | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67351102; called by muse, mutect2, varscan2
- OSBP | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.576); catalogued as COSV55661122, COSV99803275; called by muse, mutect2, varscan2
- PARP4 | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as COSV67960769; called by muse, mutect2
- PGLYRP4 | c.943+2T>C p.X315_splice | Splice Site (SNP) | VAF 50/86 reads (58%) | catalogued as COSV62834693; called by muse, mutect2, varscan2
- PIK3C2A | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV56400738, COSV56406582; called by muse, mutect2, varscan2
- PLEKHA5 | c.1855G>C p.D619H | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV54695253; called by muse, mutect2
- PLPPR4 | c.1617G>C p.E539D | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV64564599; called by muse, mutect2, varscan2
- PPP1R3B | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV60098979; called by muse, mutect2, varscan2
- PPP3CC | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1464974815, COSV51499636; called by muse, mutect2, varscan2
- PRXL2A | c.519C>G p.N173K | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1271302688, COSV64690561; called by muse, mutect2, varscan2
- PXDN | c.3320G>C p.R1107P | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571027818, COSV53227961, COSV53229933; called by muse, mutect2, varscan2
- RABGAP1L | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52279192; called by muse, mutect2, varscan2
- RALGAPA1 | c.5671G>C p.D1891H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51877622; called by muse, mutect2
- ROBO1 | c.4157G>A p.G1386E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV71392076; called by muse, mutect2, varscan2
- ROPN1L | c.359G>C p.C120S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56873096; called by muse, mutect2, varscan2
- RSRC2 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV59203138; called by muse, mutect2, varscan2
- SALL3 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs746622657, COSV73305811; called by muse, mutect2, varscan2
- SCAP | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs747668597, COSV55559214; called by muse, mutect2, varscan2
- SCN1A | c.4822G>A p.D1608N (on ENST00000303395 / NM_001202435.3; = p.D1597N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM076507, COSV57662094; called by muse, mutect2, varscan2
- SCN8A | c.5006G>A p.G1669E | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61977322; called by muse, mutect2, varscan2
- SEL1L2 | c.1270T>C p.W424R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.999); catalogued as rs1290316093, COSV53148590; called by muse, mutect2
- SMAP2 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs755011671; called by muse, mutect2, varscan2
- SPEF2 | c.2783T>C p.I928T | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61544779; called by muse, mutect2
- SPHKAP | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778045595, COSV60870233; called by muse, mutect2, varscan2
- SPTBN4 | c.4303G>C p.D1435H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV58944379; called by muse, mutect2, varscan2
- ST18 | c.649A>G p.R217G | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs772997658, COSV52485958; called by muse, mutect2, varscan2
- STK10 | c.2790G>C p.Q930H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51570977; called by muse, mutect2, varscan2
- TBCE | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV64005290; called by muse, mutect2, varscan2
- TMPRSS2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV59821554; called by muse, mutect2, varscan2
- TOB1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52149827; called by muse, mutect2, varscan2
- TRIM71 | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV67470248; called by muse, mutect2, varscan2
- TTN | c.67595T>C p.V22532A (on ENST00000591111; = p.V15108A on NM_003319.4) | Missense Mutation (SNP) | VAF 158/215 reads (73%) | PolyPhen probably damaging (0.99); catalogued as rs1260315259, COSV59911265; called by muse, mutect2, varscan2
- TTN | c.55093G>T p.G18365C (on ENST00000591111; = p.G10941C on NM_003319.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | PolyPhen probably damaging (1); catalogued as COSV59911288; called by muse, mutect2, varscan2
- USH2A | c.10627C>T p.R3543C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs769798493, COSV100235803, COSV56328573; called by muse, mutect2, varscan2
- WASHC4 | c.1253C>G p.S418C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100162248, COSV59888671; called by muse, mutect2, varscan2
- YY1AP1 | c.402G>C p.K134N (on ENST00000295566 / NM_139118.2; = p.K57N on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV55119403; called by muse, mutect2, varscan2
- ZBTB12 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV64993580; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV56271886; called by muse, mutect2, varscan2
- ZMYND8 | c.3208C>T p.Q1070* (on ENST00000311275 / NM_001363741.2; = p.Q1044* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV53698779; called by muse, mutect2, varscan2
- ZNF335 | c.3667C>T p.Q1223* | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | catalogued as COSV100533442; called by muse, mutect2
- ZNF829 | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV66985735; called by muse, mutect2, varscan2
- AHDC1 | c.2009G>A p.G670D | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- MAEL | c.793del p.W265Gfs*6 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- MECOM | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- POMGNT2 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- RIMS2 | c.2153del p.G718Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G526Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- SORCS3 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- TBL1X | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 31/37 reads (84%) | called by muse, mutect2, varscan2
- TGFBRAP1 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- TRPV5 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- UNC13C | c.5622del p.T1875Hfs*15 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- ZBTB26 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- AAK1 | c.552G>A p.L184= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV68642056; called by muse, mutect2, varscan2
- ACR | c.609C>T p.L203= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as COSV53360496; called by muse, mutect2, varscan2
- BMP1 | c.363G>A p.A121= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs755055320, COSV59244067; called by muse, mutect2, varscan2
- CCT8 | c.924T>C p.Y308= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs1212453930, COSV54503100; called by muse, mutect2, varscan2
- CCT8L2 | c.621G>A p.A207= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs774705418, COSV63461734, COSV63463561; called by muse, mutect2, varscan2
- CDK15 | c.675G>C p.L225= (on ENST00000652192 / NM_001366386.2; = p.L174= on NM_139158.2) | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV53631943; called by muse, mutect2, varscan2
- CECR2 | c.258C>T p.I86= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- CYP2F1 | c.1278C>T p.F426= | Silent (SNP) | VAF 19/177 reads (11%) | called by muse, mutect2
- DCST2 | c.1248C>T p.L416= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV55050308, COSV99792011; called by muse, mutect2, varscan2
- DCT | c.1017C>T p.F339= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV65467674; called by muse, mutect2, varscan2
- DUS2 | c.63G>T p.R21= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV62707955; called by muse, mutect2, varscan2
- EMX1 | c.732G>A p.R244= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as rs1403470941, COSV50689208; called by muse, mutect2, varscan2
- FAM71F2 | c.588G>A p.K196= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV66351903, COSV66352100; called by muse, mutect2
- FARP2 | c.927C>T p.F309= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV50869341; called by muse, mutect2, varscan2
- FOXO1 | c.1941A>G p.T647= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as rs1434940921, COSV65425479; called by muse, mutect2, varscan2
- KIF26B | c.2907G>A p.A969= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs761535050, COSV100831944, COSV63637567; called by muse, mutect2, varscan2
- LSM1 | c.336G>A p.L112= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV60948704; called by muse, mutect2, varscan2
- MAGEC1 | c.780T>C p.F260= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV53568871; called by muse, mutect2
- MBD6 | c.105C>G p.L35= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV60764897; called by mutect2, varscan2
- MBOAT7 | c.132C>T p.F44= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs568163323, COSV55474551, COSV55475550; called by muse, mutect2, varscan2
- MCTP2 | c.1545T>G p.V515= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV59141390; called by muse, mutect2, varscan2
- MIGA1 | c.318A>G p.P106= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs759392225, COSV66222933; called by muse, mutect2, varscan2
- MLEC | c.624C>G p.L208= | Silent (SNP) | VAF 27/283 reads (10%) | catalogued as COSV57329221; called by muse, mutect2, varscan2
- MROH8 | c.432C>T p.V144= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV54117761; called by muse, mutect2, varscan2
- MYO3A | c.3612C>T p.F1204= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV56321472; called by muse, mutect2, varscan2
- MYOF | c.5724C>T p.H1908= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV63700988; called by muse, mutect2, varscan2
- NOL6 | c.2751C>G p.L917= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV53039585; called by muse, mutect2, varscan2
- OR8J3 | c.729G>T p.S243= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs774862778, COSV56879581, COSV56879736; called by muse, mutect2, varscan2
- OTX1 | c.438C>T p.S146= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV56993782; called by muse, mutect2, varscan2
- PCNX1 | c.763C>T p.L255= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV53090250; called by muse, mutect2, varscan2
- PDGFB | c.468C>T p.I156= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs774559047, COSV58645992; called by muse, mutect2, varscan2
- PHOX2A | c.777C>T p.S259= | Silent (SNP) | VAF 12/14 reads (86%) | called by muse, mutect2, varscan2
- POGK | c.1188G>C p.L396= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV63311279; called by muse, mutect2, varscan2
- PRAMEF20 | c.240T>A p.A80= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV57080631; called by muse, mutect2, varscan2
- PXDN | c.3321G>T p.R1107= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV53227953; called by muse, mutect2, varscan2
- SCN8A | c.5457C>T p.L1819= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV61977348; called by muse, mutect2, varscan2
- SLC1A4 | c.1188C>G p.L396= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV52233677; called by muse, mutect2, varscan2
- SPACA7 | c.183G>A p.L61= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as COSV52098162, COSV52103329; called by muse, mutect2, varscan2
- STT3B | c.771C>T p.F257= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV55501400; called by muse, mutect2, varscan2
- STUB1 | c.840C>T p.L280= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs1335503026, COSV50196498; called by muse, mutect2, varscan2
- SYNE1 | c.25455C>G p.L8485= (on ENST00000367255 / NM_182961.4; = p.L8437= on NM_033071.3) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV54919777; called by muse, mutect2, varscan2
- TM6SF1 | c.42C>T p.L14= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs746273590, COSV51943256, COSV51946983; called by muse, mutect2, varscan2
- TOB1 | c.256C>T p.L86= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as COSV52149842; called by muse, mutect2, varscan2
- VPS13D | c.11964C>G p.L3988= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV50623970; called by muse, mutect2, varscan2
- VPS53 | c.1398C>T p.A466= (on ENST00000571805 / NM_001366253.2; = p.A437= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/32 reads (84%) | catalogued as rs1161322190, COSV52126693; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502152 ins T | 5'Flank (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- ARFRP1 | c.264+718G>A | Intron (SNP) | VAF 29/186 reads (16%) | catalogued as rs1279262209; called by muse, mutect2, varscan2
- CELF2 | c.53+12695G>A | Intron (SNP) | VAF 38/163 reads (23%) | catalogued as COSV64927784; called by muse, mutect2, varscan2
- RPL31P57 | n.216C>T | RNA (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- SNORA71C | n.109C>T | RNA (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- TMEM71 | c.814+119C>G | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as rs1563741218, COSV63456516; called by muse, mutect2, varscan2
